TCGA case TCGA-98-7454 — Lung Squamous Cell Carcinoma (TCGA-LUSC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Squamous Cell Neoplasms; Primary site: Bronchus and lung; Tissue source site: Washington University - Alabama. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/ae343aae-7273-4c46-826d-01377bed5a75

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 73 years; Vital status: Alive.

Diagnoses (1)
1. Squamous cell carcinoma, NOS: ICD-O-3 morphology code: 8070/3; ICD-10 code: C34.1; Tissue or organ of origin: Upper lobe, lung; Site of resection or biopsy: Lung, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 73.4 years (26,827 days); Year of diagnosis: 2011; AJCC staging edition: 7th; AJCC pathologic T: T2a; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IB; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 652 days (1.8 years).
   Pathology details: Consistent pathology review: Yes.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.

Follow-up (4 entries)
- Days to follow up: 115 days; Disease response: Tumor Free.
- Days to follow up: 256 days; Disease response: Tumor Free.
- Days to follow up: 652 days (1.8 years); Disease response: Tumor Free.
- Karnofsky performance status: 100; ECOG performance status: 0; Timepoint: Other.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for > 15 yrs; Pack years smoked: 60; Tobacco smoking onset year: 1943; Tobacco smoking quit year: 1983.

Biospecimens (4 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-98-7454-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 2.2; Intermediate dimension: 1.5; Shortest dimension: 0.5.
  Slide TCGA-98-7454-01A-01-BS1: Section location: Bottom; Percent tumor cells: 45; Percent tumor nuclei: 65; Percent normal cells: 25; Percent necrosis: 15; Percent stromal cells: 15.
  Slide TCGA-98-7454-01A-01-TS1: Section location: Top; Percent tumor cells: 67; Percent tumor nuclei: 75; Percent normal cells: 3; Percent necrosis: 15; Percent stromal cells: 15.
- Sample TCGA-98-7454-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-98-7454-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.
- Sample TCGA-98-7454-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Longest dimension: 1.1; Intermediate dimension: 1; Shortest dimension: 0.6.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Lung; Histologic diagnosis: Lung Squamous Cell Carcinoma- Not Otherwise Specified (NOS); History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: Tumor free; Tobacco smoking history indicator: 3; Anatomic organ subdivision: R-Upper; KRAS gene analysis indicator: Yes; EGFR mutation status: Yes; Eml4 alk translocation status: Yes.
- Follow-up form 1: New tumor event diagnosis indicator: No; Tumor status: Tumor free.
- Follow-up form 2: Lost to follow-up: No; Treatment outcome first course: Complete Remission/Response; New tumor event diagnosis indicator: No; Tumor status: Tumor free; New tumor event radiation treatment: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 652 days; disease-specific survival: no event (censored), 652 days; disease-free interval: no event (censored), 652 days; progression-free interval: no event (censored), 652 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-98-7454-01A-11D-2041-01): tumor purity 0.25, ploidy 1.62, whole-genome doublings 0.
